Somatic mutation profile of tumor specimen TARGET-10-PANTSM-04A (aliquot TARGET-10-PANTSM-04A-01D) from TARGET case TARGET-10-PANTSM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,591 days).
Specimen TARGET-10-PANTSM-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9eb4917-f7b0-4b31-a588-094fb62f8dcf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTSM-14A (Bone Marrow Normal), aliquot TARGET-10-PANTSM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d1383c1-de2d-4011-9ad4-ffb2f7b7c31d

The open-access MAF lists 45 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Intron 2, Splice Region 2, Nonsense Mutation 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 196/419 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507509, CD041931, CM021126, CX060726, COSV100692385, COSV61005028, COSV61006397; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 113/115 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.1484G>C p.R495P | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM050966, COSV56856109; called by muse, mutect2, varscan2
- CORIN | c.1619G>T p.C540F | Missense Mutation (SNP) | VAF 109/223 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770141559, COSV56697563; called by muse, mutect2, varscan2
- FBN3 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs141165450; called by muse, mutect2, varscan2
- FMR1 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 123/124 reads (99%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs376406395, COSV54426733; called by muse, mutect2, varscan2
- GALNT3 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 54/625 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67062308; called by muse, mutect2
- GANC | c.2021A>C p.Y674S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | PolyPhen probably damaging (1); catalogued as COSV58811184; called by muse, mutect2, varscan2
- GDA | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 115/242 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); catalogued as rs779961418, COSV52996796; called by muse, mutect2, varscan2
- GPR39 | c.187T>G p.Y63D | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61427671; called by muse, mutect2
- HIC2 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV68042054; called by mutect2, varscan2
- MCF2 | c.1557G>A p.L519= | Splice Region (SNP) | VAF 314/319 reads (98%) | catalogued as COSV58485784; called by muse, mutect2, varscan2
- MKI67 | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 19/306 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs149566139; called by muse, mutect2
- MORN1 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58101376; called by muse, mutect2, varscan2
- MUC21 | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs200661879, COSV66220127; called by muse, varscan2
- MYO10 | c.3921G>T p.Q1307H | Missense Mutation (SNP) | VAF 102/207 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as COSV57028488; called by muse, mutect2, varscan2
- NBPF9 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 130/309 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as rs1170634053; called by muse, mutect2, varscan2
- NCKAP1L | c.3135C>A p.F1045L | Missense Mutation (SNP) | VAF 232/460 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV53211132; called by muse, mutect2, varscan2
- NOMO2 | c.2188G>T p.E730* | Nonsense Mutation (SNP) | VAF 177/734 reads (24%) | catalogued as COSV57917941, COSV57918098; called by muse, mutect2, varscan2
- NT5C2 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 377/403 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58414749; called by muse, mutect2, varscan2
- NYAP2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56014060; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.98C>T p.P33L (on ENST00000259318 / NM_001136562.3; = p.P264L on NM_007203.5) | Missense Mutation (SNP) | VAF 179/351 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs1300488273, COSV52180474; called by muse, mutect2, varscan2
- PARD3 | c.1826G>C p.R609P | Missense Mutation (SNP) | VAF 131/310 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV60759209; called by muse, mutect2, varscan2
- PPP3CA | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 193/400 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59921756; called by muse, mutect2, varscan2
- SLC28A2 | c.864C>G p.V288= | Splice Region (SNP) | VAF 168/391 reads (43%) | catalogued as COSV61664980; called by muse, mutect2, varscan2
- SMARCB1 | c.644G>A p.R215H (on ENST00000263121; = p.R261H on NM_003073.5) | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs779587990, COSV54101534; called by muse, mutect2, varscan2
- SULT1B1 | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 188/501 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60209090; called by muse, mutect2, varscan2
- TM7SF2 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 125/253 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.19); catalogued as rs551357064, COSV54207136; called by muse, mutect2, varscan2
- TMEM14C | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 151/352 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV57639134; called by muse, mutect2, varscan2
- TTBK2 | c.3658G>C p.G1220R | Missense Mutation (SNP) | VAF 161/320 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as rs776506980, COSV51173844; called by muse, mutect2, varscan2
- ZFYVE28 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52116109; called by muse, varscan2
- HIC2 | c.1632dup p.R545Afs*21 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- ADCY4 | c.1746C>G p.P582= | Silent (SNP) | VAF 81/204 reads (40%) | catalogued as COSV60256861; called by muse, mutect2, varscan2
- CCDC166 | c.1245G>C p.P415= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV72638882; called by muse, mutect2, varscan2
- CNOT10 | c.1353G>A p.S451= | Silent (SNP) | VAF 163/337 reads (48%) | catalogued as rs147797250; called by muse, mutect2, varscan2
- CNTNAP4 | c.1404G>A p.A468= | Silent (SNP) | VAF 39/317 reads (12%) | catalogued as rs1220272321, COSV56690108, COSV56696558; called by muse, mutect2, varscan2
- CTDP1 | c.2352G>A p.T784= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs1043027; called by muse, mutect2, varscan2
- DCSTAMP | c.54C>T p.Y18= | Silent (SNP) | VAF 104/203 reads (51%) | catalogued as rs150364969; called by muse, mutect2, varscan2
- FAIM2 | c.174G>A p.A58= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs913537112, COSV57740745; called by muse, mutect2, varscan2
- LAMA1 | c.7482C>T p.G2494= | Silent (SNP) | VAF 62/147 reads (42%) | catalogued as rs369257165; called by muse, mutect2, varscan2
- TMF1 | c.2652G>C p.T884= | Silent (SNP) | VAF 201/511 reads (39%) | catalogued as COSV68375547; called by muse, mutect2, varscan2
- EIF4A2 | c.771+61C>A | Intron (SNP) | VAF 159/300 reads (53%) | catalogued as COSV56218293; called by muse, mutect2, varscan2
- MBNL2 | c.994+1314G>A | Intron (SNP) | VAF 91/181 reads (50%) | catalogued as rs138682101; called by muse, mutect2, varscan2
- XPNPEP2 | c.-16G>C | 5'UTR (SNP) | VAF 57/79 reads (72%) | catalogued as COSV64368149; called by muse, varscan2
